Somatic mutation profile of tumor specimen TCGA-KK-A7B4-01A (aliquot TCGA-KK-A7B4-01A-11D-A32B-08) from TCGA case TCGA-KK-A7B4, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 64.7 years (23,644 days).
Specimen TCGA-KK-A7B4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 76aafd63-4ce9-4c99-b355-a18a04888d5a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KK-A7B4-11A (Solid Tissue Normal), aliquot TCGA-KK-A7B4-11A-11D-A329-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ecf814e5-6f5f-4045-b454-7a90bc11b15b

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 2, Intron 1, Frame Shift Del 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.371dup p.C124Wfs*25 | Frame Shift Ins (INS) | VAF 24/55 reads (44%) | catalogued as rs1267047192, COSV53205177; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AADACL4 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 66/178 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.037); catalogued as rs201123258, COSV100879405; called by muse, mutect2, varscan2
- ACSM2B | c.894G>A p.K298= | Splice Region (SNP) | VAF 17/210 reads (8%) | catalogued as COSV61659854; called by muse, mutect2
- C12orf71 | c.598G>A p.D200N | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as rs1377083454, COSV70282498; called by muse, mutect2, varscan2
- CHRNA7 | c.431G>A p.G144D | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100181177; called by mutect2, varscan2
- CNPPD1 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 15/48 reads (31%) | catalogued as rs774728461, COSV99811535; called by muse, mutect2, varscan2
- CS | c.1165T>G p.L389V | Missense Mutation (SNP) | VAF 4/76 reads (5%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV100369968; called by muse, mutect2
- DYNC1H1 | c.307A>G p.I103V | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100794848; called by muse, mutect2, varscan2
- FAM102B | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.759); catalogued as COSV64239736; called by muse, mutect2, varscan2
- GUCY2C | c.1750T>G p.F584V | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as COSV99663614; called by muse, mutect2, varscan2
- IER5 | c.327C>G p.D109E | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100849684; called by muse, varscan2
- JTB | c.328G>A p.E110K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs747839326, COSV55133339; called by muse, mutect2, varscan2
- LRRC8B | c.2389C>A p.Q797K | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100446526; called by muse, mutect2, varscan2
- MYOCD | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58497340; called by muse, mutect2, varscan2
- NTNG1 | c.880C>T p.R294* | Nonsense Mutation (SNP) | VAF 7/70 reads (10%) | catalogued as COSV53978019; called by muse, mutect2
- OR13C3 | c.821A>T p.H274L | Missense Mutation (SNP) | VAF 56/174 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV101053314; called by muse, mutect2, varscan2
- SLC22A10 | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as rs775717347, COSV100235741; called by muse, mutect2, varscan2
- SLC39A12 | c.286C>A p.L96I | Missense Mutation (SNP) | VAF 40/108 reads (37%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.643); catalogued as COSV101070050; called by muse, mutect2, varscan2
- SPON1 | c.1049T>C p.L350P | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59957187; called by muse, mutect2
- XKR4 | c.1249G>A p.V417I | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT tolerated (1); PolyPhen possibly damaging (0.572); catalogued as rs761395206, COSV59297915; called by muse, mutect2, varscan2
- ZNF658 | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs1200922949; called by mutect2, varscan2
- LMTK2 | c.637_641delinsC p.V213Lfs*9 | Frame Shift Del (DEL) | VAF 36/133 reads (27%) | called by pindel, varscan2*
- COG1 | c.858G>T p.L286= | Silent (SNP) | VAF 25/134 reads (19%) | catalogued as COSV100245299; called by muse, mutect2, varscan2
- FAM135B | c.933G>A p.T311= | Silent (SNP) | VAF 15/55 reads (27%) | catalogued as rs376834770, COSV52720390; called by muse, mutect2, varscan2
- GALNTL6 | c.1320C>T p.D440= | Silent (SNP) | VAF 11/19 reads (58%) | catalogued as rs144094710; called by muse, mutect2, varscan2
- INAVA | c.1557G>A p.A519= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1473242364, COSV100949987; called by muse, mutect2, varscan2
- SUN3 | c.480G>A p.P160= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs150352113; called by muse, mutect2, varscan2
- TFAP2E | c.804G>A p.G268= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100951468; called by muse, mutect2, varscan2
- TRIM35 | c.558G>T p.R186= | Silent (SNP) | VAF 3/28 reads (11%) | catalogued as COSV59522637; called by muse, mutect2
- OBSCN | c.5138-1676G>A | Intron (SNP) | VAF 13/56 reads (23%) | catalogued as rs770217177, COSV52816910; called by muse, mutect2, varscan2
